Gene-level copy-number profile of tumor specimen ALCH-AEJR-TTP1-A from ALCHEMIST case ALCH-AEJR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma with mixed subtypes; Age at diagnosis: 52.7 years (19,244 days).
Specimen ALCH-AEJR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b4106034-8ee1-40be-971d-d03f237536ee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEJR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,242 have no estimate.
https://portal.gdc.cancer.gov/files/c8be7988-1e3d-4e6a-898c-133d0357529c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 352; copy number 2: 56,519; copy number 3: 1,429; copy number 4: 79; copy number 5: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,414,483–43,427,131, 1 gene, copy number 5: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 10 (within-gene range 2–10): LINC00313.

Autosomal genes at a single copy (total copy number 1): 351. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
